Somatic mutation profile of tumor specimen TCGA-D7-A6EX-01A (aliquot TCGA-D7-A6EX-01A-11D-A31L-08) from TCGA case TCGA-D7-A6EX, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.6 years (26,525 days).
Specimen TCGA-D7-A6EX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08bbc00e-4e6f-4220-9ceb-ddd8e38c672d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A6EX-10A (Blood Derived Normal), aliquot TCGA-D7-A6EX-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69806fc1-f06d-4881-873f-548b2ae24552

The open-access MAF lists 129 somatic variants for this specimen: 97 protein-altering or splice-affecting, 32 silent.
By variant classification: Missense Mutation 88, Silent 32, Nonsense Mutation 6, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 44/56 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA9 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100383309; called by muse, mutect2, varscan2
- ADAMTS10 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs782497547, COSV99547169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD26 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs766072180, COSV101066558; called by muse, mutect2, varscan2
- ARIH2 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100711375; called by muse, mutect2, varscan2
- ASAP2 | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV55637770; called by muse, mutect2, varscan2
- ASPM | c.8615C>T p.T2872M | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as rs142176273; called by muse, mutect2, varscan2
- ATP2B4 | c.832T>C p.S278P | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100397836; called by muse, mutect2
- ATP9B | c.3271T>A p.F1091I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100303895; called by muse, varscan2
- ATRX | c.4557+2T>G p.X1519_splice | Splice Site (SNP) | VAF 50/147 reads (34%) | catalogued as COSV100971170; called by muse, mutect2, varscan2
- BRF1 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100527526; called by muse, mutect2, varscan2
- CALCRL | c.479T>A p.L160H | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101131010; called by muse, mutect2, varscan2
- CATSPERD | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs750625210, COSV100486899; called by muse, mutect2, varscan2
- CD300C | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs141778260; called by muse, mutect2, varscan2
- CDS2 | c.1027T>C p.S343P | Missense Mutation (SNP) | VAF 91/175 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100986140; called by muse, mutect2, varscan2
- CDS2 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 89/174 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779759723, COSV100986142; called by muse, mutect2, varscan2
- CILP2 | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99364961; called by muse, mutect2, varscan2
- CKAP2L | c.936A>T p.R312S | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV100198676; called by muse, mutect2, varscan2
- CNST | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV100829890; called by muse, mutect2
- CNTN3 | c.2219T>A p.F740Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV99725361; called by muse, mutect2, varscan2
- COL6A3 | c.8059T>G p.F2687V | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.257); catalogued as COSV99799871; called by muse, mutect2, varscan2
- CRB2 | c.1327G>C p.V443L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100749706; called by muse, mutect2, varscan2
- CTNNA3 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV99042805; called by muse, mutect2, varscan2
- CUBN | c.9570T>G p.I3190M | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.764); catalogued as COSV100913109; called by muse, mutect2, varscan2
- CYP11B1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs764251434, CM1210436, COSV52830527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEPDC5 | c.1760G>T p.R587L | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99835948; called by muse, mutect2, varscan2
- DPP8 | c.1963G>A p.D655N (on ENST00000341861 / NM_001320875.2; = p.D639N on NM_017743.6) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100202485; called by muse, mutect2, varscan2
- DRC7 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371355067; called by muse, mutect2, varscan2
- DSCAML1 | c.1289C>T p.T430M (on ENST00000321322; = p.T370M on NM_020693.4) | Missense Mutation (SNP) | VAF 53/205 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1212445579, COSV100356533; called by muse, mutect2, varscan2
- E2F5 | c.1015T>G p.F339V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99809632; called by muse, mutect2, varscan2
- EEFSEC | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.487); catalogued as COSV99630784; called by muse, mutect2, varscan2
- EPB41L3 | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 116/442 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as rs745916851, COSV59448831; called by muse, mutect2, varscan2
- EPG5 | c.131G>T p.R44I | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.022); catalogued as COSV99957657; called by muse, mutect2, varscan2
- EPHB1 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101213615, COSV67673309; called by muse, varscan2
- FAM177B | c.349A>T p.N117Y | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV100680428; called by muse, mutect2
- FBXL3 | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV100842381; called by muse, mutect2, varscan2
- FER1L6 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV101206072; called by muse, mutect2, varscan2
- FGFR4 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99450455; called by muse, mutect2, varscan2
- FOXA3 | c.432C>G p.Y144* | Nonsense Mutation (SNP) | VAF 14/176 reads (8%) | catalogued as COSV100141453; called by muse, mutect2
- FZD7 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as rs1253159878, COSV53809673; called by muse, mutect2, varscan2
- GABRG2 | c.1268G>T p.R423L (on ENST00000361925 / NM_001375343.1; = p.R383L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs528036202, COSV62716272, COSV62721034; called by muse, mutect2, varscan2
- GAK | c.3080C>T p.S1027L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1432726628, COSV100033852; called by muse, mutect2, varscan2
- GHR | c.1895A>C p.Q632P | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100051414; called by muse, mutect2
- GOLGA2 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.966); catalogued as rs534286778, COSV100360148; called by muse, mutect2, varscan2
- HCN4 | c.3493C>A p.L1165M | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); catalogued as COSV56080986, COSV99983978; called by muse, mutect2, varscan2
- HEATR1 | c.5653G>A p.D1885N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs536014077, COSV100857721; called by muse, mutect2, varscan2
- ILK | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99601980; called by muse, mutect2, varscan2
- INF2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1012899025, COSV99384105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQCC | c.257A>T p.H86L | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV99356717; called by muse, mutect2
- ITGA4 | c.2434A>G p.I812V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.35); catalogued as COSV101223533; called by muse, mutect2, varscan2
- ITGAM | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs756564190, COSV54936900, COSV99793115; called by muse, mutect2, varscan2
- JAKMIP1 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as COSV51540748, COSV99290228; called by muse, mutect2, varscan2
- KCNV1 | c.670A>C p.I224L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV99819254; called by muse, mutect2
- KIF4B | c.215T>A p.L72H | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101469358; called by muse, mutect2, varscan2
- KIRREL1 | c.1294T>G p.F432V | Missense Mutation (SNP) | VAF 90/131 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100780018, COSV63284974; called by muse, mutect2, varscan2
- KRT12 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as rs150674571, COSV99289023; called by muse, mutect2, varscan2
- MSL1 | c.1171C>T p.R391W (on ENST00000398532 / NM_001365919.1; = p.R128W on NM_001012241.2) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs757589482, COSV59899484; called by muse, mutect2, varscan2
- MYH4 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV99701755; called by muse, mutect2, varscan2
- NCK2 | c.442T>A p.W148R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99256402; called by muse, mutect2, varscan2
- NCOA2 | c.3208G>T p.A1070S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1037021666, COSV99144969; called by muse, mutect2, varscan2
- NLRC5 | c.4720C>A p.L1574I | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV99347786; called by muse, mutect2, varscan2
- NUP214 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 79/854 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100845353; called by muse, mutect2
- OR14K1 | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 61/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99315343; called by muse, mutect2, varscan2
- OXSR1 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100309529; called by muse, mutect2, varscan2
- PCDHB14 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.251); catalogued as rs777821767, COSV53386829, COSV99505975; called by muse, mutect2, varscan2
- PCF11 | c.1764G>A p.W588* | Nonsense Mutation (SNP) | VAF 29/126 reads (23%) | catalogued as COSV53532876; called by muse, mutect2, varscan2
- PCLO | c.6634G>A p.E2212K | Missense Mutation (SNP) | VAF 32/757 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as COSV100434755; called by muse, mutect2
- PCP4L1 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV101552222; called by muse, mutect2, varscan2
- POGLUT2 | c.956T>A p.L319Q | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101050810; called by muse, mutect2, varscan2
- POLR3E | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100242261; called by muse, mutect2, varscan2
- PRLHR | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV53303441; called by muse, mutect2, varscan2
- PYHIN1 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100932378; called by muse, mutect2, varscan2
- RBM14 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV100036866, COSV59558447; called by muse, mutect2, varscan2
- RNPEP | c.1733T>G p.I578S | Missense Mutation (SNP) | VAF 150/402 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV99821705; called by muse, mutect2, varscan2
- RUNX2 | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767595; called by muse, mutect2, varscan2
- SACM1L | c.1663T>C p.F555L | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV101203781; called by muse, mutect2
- SORBS2 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV53006861; called by muse, mutect2, varscan2
- SPTA1 | c.5080C>T p.R1694C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490249015, COSV63748216; called by muse, mutect2
- SSPN | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99658768; called by muse, mutect2
- TAOK3 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101183635; called by muse, mutect2, varscan2
- TBC1D15 | c.658-2A>T p.X220_splice | Splice Site (SNP) | VAF 26/83 reads (31%) | catalogued as COSV100041997; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2353C>T p.Q785* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as rs938976339, COSV99305296; called by muse, mutect2, varscan2
- THUMPD2 | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs764475974; called by muse, mutect2, varscan2
- THUMPD2 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as rs777112640, COSV53187951; called by muse, mutect2, varscan2
- TIAM1 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 104/168 reads (62%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV54571642, COSV99737284; called by muse, mutect2, varscan2
- TPP2 | c.2026A>G p.T676A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV101060351; called by muse, varscan2
- TRIM58 | c.1154G>C p.W385S | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.909); catalogued as COSV100825200, COSV63570772; called by muse, mutect2, varscan2
- TRPA1 | c.2987G>A p.R996H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs142468969, COSV51578002; called by muse, mutect2, varscan2
- TTN | c.63130G>T p.D21044Y (on ENST00000591111; = p.D13620Y on NM_003319.4) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | PolyPhen possibly damaging (0.515); catalogued as COSV100621261, COSV60418630; called by muse, mutect2, varscan2
- VPS13B | c.10588C>T p.R3530W | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763017122, COSV62150324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR6 | c.3223C>T p.H1075Y | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV100556562; called by muse, mutect2, varscan2
- YWHAE | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 84/109 reads (77%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV99981384; called by muse, mutect2, varscan2
- ZER1 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.249); catalogued as rs774299730, COSV52567774, COSV99402247; called by muse, mutect2
- ZNF385B | c.699C>A p.N233K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.087); catalogued as COSV100416236; called by muse, mutect2, varscan2
- ZNF658 | c.403dup p.I135Nfs*4 | Frame Shift Ins (INS) | VAF 7/46 reads (15%) | catalogued as rs1235726749; called by mutect2, pindel, varscan2
- GPR179 | c.3007G>T p.A1003S (on ENST00000621958; = p.A1002S on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2
- ADCY8 | c.1752T>G p.T584= | Silent (SNP) | VAF 42/198 reads (21%) | catalogued as COSV53899574, COSV53915819; called by muse, mutect2, varscan2
- BCL9 | c.1980G>A p.R660= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV99325554; called by muse, mutect2, varscan2
- CBLN4 | c.321A>T p.T107= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV50354234, COSV50354943; called by muse, mutect2, varscan2
- CCDC60 | c.792C>A p.P264= | Silent (SNP) | VAF 126/250 reads (50%) | catalogued as rs768918439, COSV100555432; called by muse, mutect2, varscan2
- CCDC85A | c.984C>T p.H328= | Silent (SNP) | VAF 74/206 reads (36%) | catalogued as rs766118772, COSV68152936; called by muse, mutect2, varscan2
- DIO3 | c.891C>T p.H297= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs1457085373, COSV100832181; called by muse, mutect2, varscan2
- DLGAP2 | c.348G>A p.A116= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1203600581, COSV70095706; called by muse, mutect2, varscan2
- DOCK3 | c.5100C>T p.D1700= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs774023451, COSV99813681; called by muse, varscan2
- DPYSL5 | c.831G>A p.T277= | Silent (SNP) | VAF 146/252 reads (58%) | catalogued as rs1315531182, COSV56514402; called by muse, mutect2, varscan2
- FCGBP | c.10446C>T p.G3482= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs778297878; called by muse, mutect2, varscan2
- FREM2 | c.7863C>T p.S2621= | Silent (SNP) | VAF 127/149 reads (85%) | catalogued as COSV99749727; called by muse, mutect2, varscan2
- MPEG1 | c.741C>G p.T247= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs372290102, COSV99915699, COSV99915921; called by muse, mutect2, varscan2
- MYO6 | c.810T>C p.N270= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100889387; called by muse, mutect2, varscan2
- NAF1 | c.192G>A p.E64= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- NLRC3 | c.474C>T p.F158= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs547058160, COSV57090947, COSV57091002; called by muse, mutect2, varscan2
- OXSR1 | c.1068A>G p.Q356= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as rs761933631, COSV100309530; called by muse, mutect2, varscan2
- PCDHA5 | c.1458C>T p.N486= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs1423575450, COSV65356535; called by muse, mutect2, varscan2
- PCED1B | c.546G>T p.R182= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV71394858; called by muse, mutect2, varscan2
- PCNX2 | c.2901G>C p.G967= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99268628; called by muse, mutect2
- PIGG | c.1563G>C p.V521= (on ENST00000453061 / NM_001127178.3; = p.V513= on NM_017733.4) | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV56319011, COSV99574115; called by muse, mutect2, varscan2
- PPIE | c.276C>T p.S92= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs750149944, COSV100180144; called by muse, mutect2, varscan2
- PTPRD | c.2154C>T p.V718= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs752774320, COSV100645744, COSV61963512; called by muse, mutect2, varscan2
- RNF10 | c.930C>T p.S310= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs1565958581, COSV100378814; called by muse, mutect2, varscan2
- RUNDC3B | c.621G>T p.G207= | Silent (SNP) | VAF 233/375 reads (62%) | catalogued as COSV56690148; called by muse, mutect2, varscan2
- SCARA3 | c.798C>T p.R266= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100106935; called by muse, mutect2, varscan2
- SSPN | c.303C>T p.G101= | Silent (SNP) | VAF 19/321 reads (6%) | catalogued as COSV54380889; called by muse, mutect2
- STRIP1 | c.1185G>A p.T395= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs757426185, COSV100873978; called by muse, mutect2, varscan2
- SYNRG | c.3417G>A p.L1139= | Silent (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- TASOR2 | c.768T>G p.S256= | Silent (SNP) | VAF 56/254 reads (22%) | catalogued as COSV100050714; called by muse, mutect2, varscan2
- TOX | c.831C>T p.A277= | Silent (SNP) | VAF 59/199 reads (30%) | catalogued as rs549813687, COSV63847709; called by muse, mutect2, varscan2
- TUBE1 | c.369G>A p.Q123= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100898310; called by muse, mutect2, varscan2
- ZNF503 | c.1536C>T p.L512= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as rs780511649, COSV100998028; called by muse, mutect2, varscan2
